Gene-level copy-number profile of tumor specimen TCGA-BR-A4QI-01A from TCGA case TCGA-BR-A4QI, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 71.0 years (25,928 days).
Specimen TCGA-BR-A4QI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.1ab55449-a011-44ca-9a7b-00a946a68eab.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-A4QI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/880cf0a1-a005-4085-be04-f2aed07b9cce

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 240; copy number 1: 2,992; copy number 2: 20,257; copy number 3: 17,805; copy number 4: 9,392; copy number 5: 3,794; copy number 6: 2,641; copy number 7: 1,203; copy number 8: 809; copy number 9: 280; copy number 10: 98; copy number 11: 34; copy number 12: 195; copy number 13: 36; copy number 15: 27; copy number 16: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-A4QI-01A-12D-A253-01): tumor purity 0.53, ploidy 3.05, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 114 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:60,346,478–62,598,449, 16 genes: AC009081.2, AC018554.1, NPAP1L, AC009081.1, GNPATP, AC009169.1, RPS27AP16, AC092125.2, CDH8, AC092125.1, RN7SKP76, AC012174.1, RNU6-21P, AC009161.2, AC009161.1, AC009110.1.
- chr17:26,981,694–27,058,221, 5 genes: AC069061.1, AC069061.2, PDLIM1P3, GTF2IP6, VN1R71P.
- chr21:14,027,419–14,144,468, 1 gene (within-gene range 0–1): AP001347.1.
- chr21:14,108,813–20,430,762, 92 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,976 genes in 143 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:153,203,430–154,870,281, 97 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:182,378,098–184,754,907, 52 genes, copy number 5: GLUL, TEDDM1, LINC00272, RGSL1, AL139344.1, TEDDM2P, RNASEL, Metazoa_SRP, RGS16, LINC01686, RGS8, LINC01688, AL353778.1, NPL, AL355999.1, DHX9, SHCBP1L, HMGN1P4, 5S_rRNA, AL450304.1, KRT18P28, RNU6-41P, LAMC1, LAMC1-AS1, LAMC2, NMNAT2, AL354953.1, RPS3AP8, AL449223.1, SMG7-AS1, SMG7, NCF2, AL137800.1, ARPC5, RGL1, APOBEC4, AL157899.1, AL590422.1, COLGALT2, TSEN15, AL158011.1, Y_RNA, Y_RNA, AL445228.1, RN7SL654P, AL445228.2, C1orf21, AL078645.1, AL078645.2, AL713852.1, AL713852.2, EDEM3.
- chr2:8,461,703–10,689,987, 53 genes, copy number 5 (within-gene range 3–5): LINC01814, AC092617.1, AC011747.1, SNRPEP5, ID2-AS1, ID2, KIDINS220, MBOAT2, HMGB1P25, RPL30P3, AC093904.2, AC093904.4, AC093904.3, AC093904.1, ASAP2, EIF1P7, ITGB1BP1, CPSF3, IAH1, ADAM17, AC080162.1, AC073195.1, YWHAQ, Y_RNA, AC082651.1, AC082651.4, RNU4-73P, AC082651.2, AC082651.3, TAF1B, AC010969.2, AC010969.3, GRHL1, AC010969.1, AC104794.4, AC104794.3, KLF11, AC104794.5, CYS1, AC104794.2, AC104794.1, RRM2, AC007240.1, MIR4261, RN7SL66P, AC007240.3, AC007240.2, HPCAL1, ODC1, SNORA80B, ODC1-DT, NOL10, AC007314.1.
- chr2:12,780,593–35,284,997, 373 genes, copy number 5–11 (broad region; genes not listed).
- chr2:73,640,723–74,893,359, 69 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr2:85,685,175–87,767,359, 57 genes, copy number 5 (within-gene range 3–5): GNLY, GPR160P1, RNU1-38P, ATOH8, MIR6071, AC105053.1, RN7SKP83, ST3GAL5, ST3GAL5-AS1, AC012511.1, AC012511.2, POLR1A, PTCD3, SNORD94, IMMT, Y_RNA, MIR4779, AC009309.1, MRPL35, REEP1, U8, AC009408.1, KDM3A, CHMP3, RNF103-CHMP3, RNU6-640P, AC015971.1, RNF103, RMND5A, CD8A, CD8B, ANAPC1P1, AC111200.1, RGPD1, WBP1P1, NDUFB4P5, PLGLB1, ANAPC1P2, ANAPC1P2, AC092651.1, AC092651.2, ANAPC1P3, AC083899.1, MIR4771-1, CENPNP1, LINC01955, DBF4P3, AC068279.2, IGKV3OR2-268, AC068279.1, LINC01943, CYTOR, AC133644.2, AC133644.1, PAFAH1B1P1, MIR4435-1, RPS14P5.
- chr2:199,760,544–201,619,178, 64 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:138,482,065–178,385,479, 589 genes, copy number 5–11 (broad region; genes not listed).
- chr5:16,428,536–45,895,970, 425 genes, copy number 5–16 (broad region; genes not listed).
- chr6:27,890,315–28,923,988, 60 genes, copy number 12: H3C12, H2AC17, H2BC17, RNU7-26P, OR2B2, OR2W6P, OR2B6, RPLP2P1, OR2W4P, IQCB2P, ZSCAN16-AS1, U3, OR2W2P, OR2B7P, OR2B8P, OR1F12, AL121944.1, ZNF165, ZSCAN12P1, ZNF602P, ZSCAN16, AL358933.1, ZKSCAN8, ZNF192P1, AL022393.1, ZNF603P, ZNF192P2, TOB2P1, ZSCAN9, ZKSCAN4, NKAPL, ZSCAN26, AL021997.2, PGBD1, AL021997.1, SMIM15P2, ZSCAN31, ZKSCAN3, ZSCAN12, RNU2-45P, ZSCAN23, COX11P1, OR2E1P, Z98745.2, Z98745.1, GPX6, GPX5, ZBED9, AL049543.1, AL121932.1, AL121932.2, LINC00533, RPSAP2, NOP56P1, AL662890.1, LINC01623, RPL13P, ZNF90P2, HCG14, TRIM27.
- chr6:30,102,897–31,180,731, 76 genes, copy number 6 (broad region; genes not listed).
- chr6:39,881,804–60,942,327, 372 genes, copy number 5–13 (within-gene range 4–13) (broad region; genes not listed).
- chr6:127,708,072–143,059,682, 238 genes, copy number 5–12 (within-gene range 3–12) (broad region; genes not listed).
- chr7:70,972–63,790,098, 1,121 genes, copy number 5–9 (within-gene range 3–9) (broad region; genes not listed).
- chr7:66,474,556–68,319,676, 46 genes, copy number 6: AC008267.7, AC008267.5, AC008267.6, GS1-124K5.4, AC008267.1, AC008267.3, AC006001.3, AC006001.4, SAPCD2P3, AC006001.1, RPL35P5, KCTD7, AC027644.4, AC006001.2, RABGEF1, AC027644.3, AC027644.2, GTF2IRD1P1, AC027644.1, GTF2IP23, RNU6-1254P, LINC02604, AC073335.1, Metazoa_SRP, TMEM248, RN7SL43P, SBDS, TYW1, AC073089.1, MIR4650-1, SPDYE21, PMS2P4, Y_RNA, STAG3L4, AC006480.1, AC006480.2, MTATP6P21, MTCO3P41, AC005482.1, AC092648.1, AC092637.1, AC006013.1, MTCO1P57, AC093655.1, AC093655.2, MTND4P3.
- chr7:99,546,300–101,139,247, 106 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:38,970,360–43,674,591, 111 genes, copy number 5–11 (broad region; genes not listed).
- chr8:51,257,688–88,019,113, 555 genes, copy number 5–13 (broad region; genes not listed).
- chr8:99,796,615–125,367,120, 350 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr8:134,673,131–145,066,685, 241 genes, copy number 5–8 (broad region; genes not listed).
- chr10:44,712–38,783,108, 675 genes, copy number 5–10 (broad region; genes not listed).
- chr11:16,777,297–18,939,721, 78 genes, copy number 5 (broad region; genes not listed).
- chr12:55,158,847–56,362,857, 93 genes, copy number 5–10 (broad region; genes not listed).
- chr13:25,206,049–29,505,947, 80 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr13:48,653,711–50,906,856, 48 genes, copy number 6 (within-gene range 3–6): CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L, SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11, EBPL, KPNA3, AL136301.1, RNY4P30, CTAGE10P, RNY4P9, SPRYD7, DLEU2, TRIM13, MIR3613, KCNRG, AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5, DLEU1, AL137060.6, RPL18P10, AL137060.1, AL137060.3, ST13P4, RPL34P26, AL158195.1, DLEU7, RNA5SP28.
- chr14:32,934,396–39,388,513, 120 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr14:49,373,966–50,962,002, 65 genes, copy number 8 (broad region; genes not listed).
- chr14:66,507,407–68,869,951, 50 genes, copy number 5 (within-gene range 4–5): GPHN, AL133241.1, AL049835.1, FAM71D, SF3B4P1, MPP5, AL135978.1, ATP6V1D, Y_RNA, EIF2S1, PLEK2, MIR5694, TMEM229B, PLEKHH1, PIGH, AL132640.1, AL132640.2, AL132640.3, Y_RNA, ARG2, AL049779.4, VTI1B, COX7A2P1, RNA5SP386, AL049779.1, RDH11, RDH12, RN7SL369P, RPL21P9, ZFYVE26, AL049779.3, RN7SL213P, AL049779.2, RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6, AL121820.3, AL121820.2, AL121820.1, RPL12P7, AL133313.1, AL132986.1, RNU6-921P, ZFP36L1, MAGOH3P, BLZF2P.
- chr14:73,949,926–77,653,055, 122 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr15:87,638,688–92,331,037, 137 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr15:93,035,273–97,875,650, 74 genes, copy number 5–10 (within-gene range 3–10) (broad region; genes not listed).
- chr16:66,301,809–68,358,584, 132 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr17:15,976,560–18,110,463, 104 genes, copy number 6 (broad region; genes not listed).
- chr17:37,162,616–43,610,338, 359 genes, copy number 5–10 (within-gene range 4–10) (broad region; genes not listed).
- chr17:78,130,770–80,035,872, 58 genes, copy number 8 (within-gene range 2–8): TMC8, C17orf99, EIF5AP2, SYNGR2, TK1, AFMID, AC087645.1, BIRC5, TMEM235, AC087645.4, THA1P, AC087645.3, LINC01993, AC087645.2, SOCS3, AC061992.2, RN7SL236P, PGS1, AC061992.1, DNAH17, DNAH17-AS1, AC016182.1, RN7SL454P, SCAT1, CYTH1, AC099804.1, RNU6-638P, USP36, AC022966.2, RPL9P29, TIMP2, AC022966.1, CEP295NL, AC100788.2, AC100788.1, LGALS3BP, CANT1, C1QTNF1-AS1, C1QTNF1, ENGASE, RBFOX3, AC021534.1, AC233701.1, MIR4739, LINC02078, ENPP7, CBX2, CBX8, AC100791.2, LINC01977, CBX4, AC100791.1, LINC01979, LINC01978, TBC1D16, AC100791.3, AC116025.2, AC116025.1.
- chr19:571,277–3,131,398, 166 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr19:33,080,899–35,964,063, 149 genes, copy number 7–9 (broad region; genes not listed).
- chr19:44,112,181–46,789,043, 151 genes, copy number 6–12 (broad region; genes not listed).
- chr20:37,903,111–40,758,636, 59 genes, copy number 6: VSTM2L, RN7SKP185, TTI1, RPRD1B, RN7SL237P, AL031651.1, TGM2, KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI, LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1, Metazoa_SRP, SLC32A1, ACTR5, RN7SKP173, PPP1R16B, RN7SL116P, FAM83D, AL023803.2, AL023803.1, DHX35, AL023803.3, NPM1P19, LINC01734, AL035251.1, ATG3P1, RN7SL680P, AL132981.1, AL118523.1, HSPE1P1, LINC01370, AL133419.1, AL009050.1, MAFB, AL035665.1, AL035665.2.
- chr20:56,205,052–58,715,410, 63 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,381. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
